MMRF case MMRF_1911 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/465022e3-bb64-4fd2-a28a-6191b73d01b6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.9 years (19,703 days); ISS stage: I; Days to last known disease status: 1,074 days (2.9 years); Days to last follow up: 1,074 days (2.9 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 91 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 213 days; Days to treatment end: 317 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 360 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,074.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 250 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 5.8 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.365 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 7.48 mmol/L; C-Reactive Protein 1.51 mg/dL.
- Day 70 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 4.79 g/L; Immunoglobulin A 0.716 g/L; Immunoglobulin M 0.817 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 7.87 mmol/L.
- Day 164 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 6.91 g/L; Immunoglobulin A 0.632 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 7.54 mmol/L.
- Day 246: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0 mg/dL; Immunoglobulin G 8.01 g/L; Immunoglobulin A 0.818 g/L; Immunoglobulin M 0.281 g/L; Lactate Dehydrogenase 3.85 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.08 mmol/L; Albumin 30 g/L; Glucose 7.59 mmol/L.
- Day 360: Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 5.5 g/dL; Glucose 9.57 mmol/L.
- Day 465: Hemoglobin 7.81 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Glucose 11.1 mmol/L.
- Day 542 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 5.46 g/L; Immunoglobulin A 0.846 g/L; Immunoglobulin M 0.245 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 10.1 mmol/L.
- Day 640 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Glucose 9.3 mmol/L.
- Day 724 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Hemoglobin 8.18 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Glucose 7.98 mmol/L.
- Day 824 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Hemoglobin 8.49 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Glucose 7.81 mmol/L.
- Day 906 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Hemoglobin 9.42 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Glucose 9.3 mmol/L.
- Day 990 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Hemoglobin 8.49 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.15 mmol/L; Glucose 8.86 mmol/L.

Other clinical attributes
- Day -12: Weight: 97 kg; Height: 169 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1911_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1911_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
